MMRF case MMRF_2485 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/0afc2090-c198-4ca6-b0c4-cb93b10b01f6

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 60 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 60.6 years (22,150 days); ISS stage: III; Days to last known disease status: 727 days (2.0 years); Days to last follow up: 727 days (2.0 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 238 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 291 days; Days to treatment end: 291 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 292 days; Days to treatment end: 292 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 434 days (1.2 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 0 (ECOG 1): M Protein 4.62 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 588 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.03 mg/dL; Immunoglobulin G 62.7 g/L; Immunoglobulin A 0.06 g/L; Immunoglobulin M 0.05 g/L; Beta 2 Microglobulin 13.1 µg/mL; Lactate Dehydrogenase 6.55 µkat/L; Hemoglobin 4.59 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 92 ×10⁹/L; Creatinine 194 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 1.9 mmol/L; Albumin 32 g/L; Total Protein 11.1 g/dL; Glucose 6.88 mmol/L; C-Reactive Protein 0.126 mg/dL.
- Day 98 (ECOG 1): M Protein 0.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 55.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.13 mg/dL; Immunoglobulin G 14.6 g/L; Immunoglobulin A 0.07 g/L; Immunoglobulin M 0.11 g/L; Hemoglobin 6.32 mmol/L; Leukocytes 3.1 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 134 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.38 mmol/L; Albumin 38 g/L; Total Protein 7 g/dL; Glucose 5.06 mmol/L.
- Day 182 (ECOG 1): M Protein 0.24 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 19.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.12 mg/dL; Immunoglobulin G 5.52 g/L; Immunoglobulin A 0.06 g/L; Immunoglobulin M 0.06 g/L; Hemoglobin 5.77 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 142 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.38 mmol/L; Albumin 39 g/L; Total Protein 6.4 g/dL; Glucose 5.72 mmol/L.
- Day 252 (ECOG 1): M Protein 0.08 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 16.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.16 mg/dL; Immunoglobulin G 2.66 g/L; Immunoglobulin A 0.06 g/L; Immunoglobulin M 0.04 g/L; Hemoglobin 4.9 mmol/L; Leukocytes 2.7 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 166 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.3 mmol/L; Albumin 36 g/L; Total Protein 6.1 g/dL; Glucose 5.34 mmol/L.
- Day 364 (ECOG 0): Hemoglobin 6.45 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 141 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.5 mmol/L; Albumin 40 g/L; Total Protein 6.1 g/dL; Glucose 7.32 mmol/L.
- Day 462 (ECOG 1): M Protein 0.08 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.22 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.64 mg/dL; Immunoglobulin G 5.49 g/L; Immunoglobulin A 0.07 g/L; Immunoglobulin M 0.49 g/L; Hemoglobin 6.32 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 147 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.28 mmol/L; Albumin 40 g/L; Total Protein 6.7 g/dL; Glucose 5.45 mmol/L.
- Day 546 (ECOG 1): M Protein 0.05 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.64 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.93 mg/dL; Immunoglobulin G 4.89 g/L; Immunoglobulin A 0.06 g/L; Immunoglobulin M 0.3 g/L; Hemoglobin 5.58 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 157 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.33 mmol/L; Albumin 37 g/L; Total Protein 6.2 g/dL; Glucose 5.61 mmol/L.
- Day 636 (ECOG 1): M Protein 0.14 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.85 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.04 mg/dL; Immunoglobulin G 5.11 g/L; Immunoglobulin A 0.12 g/L; Immunoglobulin M 0.32 g/L; Lactate Dehydrogenase 2.37 µkat/L; Hemoglobin 4.65 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 173 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.3 mmol/L; Albumin 37 g/L; Total Protein 6.4 g/dL; Glucose 5.39 mmol/L.
- Day 727: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.09 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.92 mg/dL; Immunoglobulin G 6.81 g/L; Immunoglobulin A 0.28 g/L; Immunoglobulin M 0.4 g/L; Hemoglobin 6.63 mmol/L; Leukocytes 2.7 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 156 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.2 mmol/L; Albumin 40 g/L; Total Protein 6.5 g/dL; Glucose 7.04 mmol/L.

Other clinical attributes
- Day 0: Weight: 74 kg; Height: 151 cm.

Family history
- Relative with cancer history: yes; Relationship type: Child.
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Breast Cancer; Relationship sex at birth: female.
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Breast Cancer.

Biospecimens (2 samples)
- Sample MMRF_2485_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 0 days.
- Sample MMRF_2485_2_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 0 days.
